TCGA case TCGA-24-1564 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d77ef9cf-f8e6-4ee9-8d4f-1106885f6b06

Demographics
Sex at birth: female; Race: white; Age at index: 67 years; Vital status: Dead; Days to death: 787 days (2.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,668 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 116 days; Number of cycles: 6; Treatment dose: 779 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 116 days; Number of cycles: 6; Treatment dose: 1,396 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Amifostine + Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 248 days; Days to treatment end: 295 days; Number of cycles: 4; Treatment dose: 5,080 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 248 days; Days to treatment end: 295 days; Number of cycles: 4; Treatment dose: 1,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 333 days; Days to treatment end: 406 days (1.1 years); Number of cycles: 4; Treatment dose: 33 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 435 days (1.2 years); Days to treatment end: 463 days (1.3 years); Number of cycles: 2; Treatment dose: 136 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 499 days (1.4 years); Days to treatment end: 568 days (1.6 years); Number of cycles: 11; Treatment dose: 1,496 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 589 days (1.6 years); Days to treatment end: 624 days (1.7 years); Number of cycles: 2; Treatment dose: 1,500 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 589 days (1.6 years); Days to treatment end: 624 days (1.7 years); Number of cycles: 2; Treatment dose: 2,462 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 736 days (2.0 years); Treatment dose: 20 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 68.1 years (24,889 days); Days to diagnosis: 221 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 221 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 221 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 787 days (2.2 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-24-1564-01A-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
  Slide TCGA-24-1564-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20.
- Sample TCGA-24-1564-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Amitostine.
- Drug treatment 5: Pharmaceutical therapy drug name: VP16; Therapy regimen: Progression.
- Drug treatment 5, Route of administrations: Route of administration: PO.
- Drug treatment 6: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Gezmar; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 787 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 787 days; disease-free interval: event (new tumor event after initially disease-free), 221 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 221 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1564-01A-01D-0497-01): tumor purity 0.41, ploidy 2.9, whole-genome doublings 1.
